Surgical pathology report (de-identified scan), TCGA case TCGA-PK-A5HA, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University Health Network, specimen TCGA-PK-A5HA-01A (Primary Tumor).

[page 1 of 2]
LABORATORY MEDICINE PROGRAM

ICD-6-3

Carcinoma, Adrenal Cortical

8370/3

Site: (L) Adrenal Gland, cortex

C74.2

4/1/8/13

Surgical Pathology Consultation Report

Patient Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED]
Gender: M
HCN: [REDACTED]
Ordering MD: [REDACTED]
Copy To: [REDACTED]

Service: [REDACTED]
Visit #: [REDACTED]
Location: [REDACTED]
Facility: [REDACTED]

Accession #: [REDACTED]
Collected: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

Specimen(s) Received

1. Adrenal: resection adrenal mass left
2. Fat

Diagnosis

1. Adrenal cortical carcinoma: Adrenal
No pathological diagnosis: Lymph node, periaudrenal
- (left) adrenalectomy specimen
2. No pathological diagnosis: Adipose tissue, (site not listed) excisional biopsy

Comment

The morphological and immunohistochemical features are consistent with an adrenocortical carcinoma.

Synoptic Data

Neoadjuvant Therapy:	No
Clinical History:	Other: left side pain.
Tumor Site:	Adrenal structure
Adrenal Gland Received:	Fresh
Procedure:	Adrenalectomy, total
Specimen Integrity:	Intact
Specimen Size:	Greatest dimension: 7.0 cm
	Additional dimension: 6.0 cm
	Additional dimension: 5.0 cm
Specimen Laterality:	Left
Tumor Size:	Greatest dimension: 5.0 cm
	Additional dimension: 4.4 cm
	Additional dimension: 4.0 cm
	Tumor gland weight: 47.3 g
Histologic Type:	Adrenal cortical carcinoma
Margins:	Margins uninvolved by tumor
Treatment Effect:	Not identified
Lymph-Vascular Invasion:	Present, small vessel (capillary lymphatic)
Perineural Invasion:	Not identified
Ancillary Studies:	Types: IHC
	Results: The tumor is strongly positive for calretinin, synaptophysin and Melan A (A103). There is variable positivity for LMWK (CAM 5.2), inhibin, CD10

[page 2 of 2]
Surgical Pathology Consultation Report

(cytoplasmic) and p53. Stains for EMA, S100, and chromogranin are negative.
MIB-1 LI is 20%.

TNM Descriptors: Not applicable

Primary Tumor (pT): pT1: Tumor 5 cm or less in greatest dimension, no extra-adrenal invasion

Regional Lymph Nodes (pN): pN0: No regional lymph node metastasis
Number of Nodes examined: 1
Number of Nodes involved: 0

Distant Metastasis (pM): Not applicable

Additional Pathologic Findings: Tumor necrosis
Degenerative changes, Hemorrhage

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Clinical History

Left adrenal adenoma

Gross Description

1. The specimen labeled with the patient's name and as "resection adrenal gland mass left" contains an adrenal gland with surrounding fibroadipose tissue. The specimen measures 7.0 x 6.0 x 5.0 cm and weighs 70.2 g. The surface is painted with silver nitrate and the fat is removed. The adrenal gland measures 5.2 x 4.0 x 5.0 cm and weighs 47.3 g. On section, there is a well-circumscribed multilobulated mass that measures 4.4 x 4.0 x 5.0 cm. The cut surface of the tumor has a variegated light brown to tan color, solid and firm. The rest of the adrenal tissue is unremarkable grossly. The tumor and normal tissue are stored frozen. The adrenal tissue is submitted as follows:

1A-AG adrenal gland serially sectioned and submitted in toto

2. The specimen labeled with the patient's name and as "fat" contains a single piece of a grossly unremarkable fibroadipose tissue that measures 5.5 x 2.2 x 1.7 cm.

2A representative sections

Microscopic Description

Fuhrman Nuclear Grade: IV

Necrosis: Present, predominantly single cell necrosis

Mitotic activity: >5 mitoses /50 high power fields

Atypical mitosis: Present

Growth pattern: Solid and diffuse

Cell type: Eosinophilic, > %90

Lymphovascular invasion: Present, sinusoidal type

Capsule invasion: Present, focal

Immunohistochemistry: The tumor is strongly positive for calretinin, synaptophysin and Melan A (A103). There is variable positivity for LMWK (CAM 5.2), inhibin, CD10 (cytoplasmic) and p53. Stains for EMA, S100, and chromogranin are negative. MIB-1 LI is 20%.

Source: NCI Genomic Data Commons file 616b000a-853b-45ee-9e4c-bc3613514098 (TCGA-PK-A5HA.B98EC873-CB6D-4395-A473-C46EC4D2DB00.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).